Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A0ZA, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A0ZA-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Multinodular goiter.
PROCEDURE: Total thyroidectomy.
SPECIFIC CLINICAL QUESTION: Not answered.
OUTSIDE TISSUE DIAGNOSIS: Not answered.
PRIOR MALIGNANCY: Not answered.
CHEMORADIATION: Not answered.
ORGAN TRANSPLANT: Not answered.
IMMUNOSUPPRESSION: Not answered.
OTHER DISEASES: Not answered.

**FINAL DIAGNOSIS:****PART 1: THYROID, TOTAL THYROIDECTOMY (11.3 GRAMS) -****A. PAPILLARY THYROID CARCINOMAS, TWO FOCI:**

- LEFT LOBE-ENCAPSULATED FOLLICULAR VARIANT (3.0 CM), CONFINED TO THYROID, NO CAPSULAR OR ANGIOLYMPHATIC INVASION.
- RIGHT LOBE-MICROCARCINOMA, (LESS THAN 0.1 CM), CONFINED TO THYROID, NO ANGIOLYMPHATIC INVASION.

B. PATHOLOGIC STAGE: pT2 N0.

C. MULTINODULAR HYPERPLASIA.

D. CHRONIC LYMPHOCYTIC THYROIDITIS.

**PART 2: LYMPH NODE, CENTRAL COMPARTMENT, BIOPSY -
TWO LYMPH NODES, NO TUMOR PRESENT (0/2).****CASE SYNOPSIS:****SYNOPTIC DATA - PRIMARY THYROID TUMORS**

SPECIMEN TYPE: Total Thyroidectomy
TUMOR SITE: Right Lobe, Left Lobe
TUMOR FOCALITY: Multifocal
TUMOR SIZE (largest nodule): Greatest Dimension: 3 cm
HISTOLOGIC TYPE: Papillary carcinoma, follicular variant
PATHOLOGIC STAGING (pTNM): pT2
pN0
Number of regional lymph nodes examined: 2
Number of regional lymph nodes involved: 0
pMX
MARGINS: Margins uninvolved by carcinoma
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L): Absent
ADDITIONAL PATHOLOGIC FINDINGS: Thyroiditis

ICD-0-3

carcinoma, papillary, follicular variant 8340/3
Site: thyroid, nos C73.9 w 11/27/11

Source: NCI Genomic Data Commons file 5a3827b1-8621-4a76-9a72-f53212d928c2 (TCGA-BJ-A0ZA.01ABC869-F3BE-4420-AB0D-D766DBE5CE71.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).